Surgical pathology report (de-identified scan), TCGA case TCGA-4L-AA1F, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Proteogenex, Inc., specimen TCGA-4L-AA1F-01A (Primary Tumor).

Age/Sex: / M

Date:

Procedure: Radical prostatectomy

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
9/21/14

Preoperative diagnosis: CARCINOMA OF THE PROSTATE

Postoperative diagnosis: SEE MICROSCOPIC DIAGNOSIS BELOW

Specimen(s): 1. PROSTATE 2. LEFT PELVIC LYMPH NODES 3. RIGHT PELVIC LYMPH NODES

Diagnosis:

1. PROSTATE:

- Acinar adenocarcinoma, Gleason score 8 (4+4)
- Tumor involves both lobes and seminal vesicles
- Perineural and vascular invasion is present
- Extracapsular invasion is not identified
- Resection margins are positive for tumor

2. LEFT PELVIC LYMPH NODES:

- All (two) lymph nodes are negative for metastatic carcinoma

3. RIGHT PELVIC LYMPH NODES:

- All (two) lymph nodes are negative for metastatic carcinoma

Gross description:

1. PROSTATE:

Received fresh, is a prostate 5.0 x 4.0 x 4.0 cm in dimensions with seminal vesicles. The prostate has a firm lobulated gray cut surface.

2. LEFT PELVIC LYMPH NODES:

Received fresh, is a portion of adipose tissue with two lymph nodes to 1.0 cm in greatest dimension.

3. RIGHT PELVIC LYMPH NODES:

Received fresh, is a portion of adipose tissue with two lymph nodes to 1.0 cm in greatest dimension.

Source: NCI Genomic Data Commons file e9fddd36-eb64-4c61-831c-1486ab9f78a2 (TCGA-4L-AA1F.A9DCC04F-A189-408C-9EE0-9F36F388068D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).